Somatic mutation profile of tumor specimen TCGA-D6-A6EM-01A (aliquot TCGA-D6-A6EM-01A-21D-A31L-08) from TCGA case TCGA-D6-A6EM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.3 years (23,865 days).
Specimen TCGA-D6-A6EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba6c3a95-46d4-49b5-bccb-1e948ff6c4ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6EM-10A (Blood Derived Normal), aliquot TCGA-D6-A6EM-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/929bfe86-83b6-4078-8171-4cb575b4af7d

The open-access MAF lists 97 somatic variants for this specimen: 78 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 18, Nonsense Mutation 4, Splice Site 3, Frame Shift Ins 3, Splice Region 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 121/262 reads (46%) | hotspot (GDC flag); catalogued as COSV53205039, COSV99285668; called by muse, mutect2, varscan2
- AC018630.4 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV99958589; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4867G>A p.D1623N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs750437275, COSV99718908; called by muse, mutect2, varscan2
- ADGRL1 | c.1160A>G p.Y387C (on ENST00000340736 / NM_001008701.3; = p.Y382C on NM_014921.5) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100529884; called by muse, mutect2, varscan2
- AL645922.1 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV54960083; called by muse, mutect2, varscan2
- ALKAL1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs370015105; called by muse, mutect2, varscan2
- ALS2CL | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420355279, COSV59671837, COSV59671997; called by muse, mutect2, varscan2
- ANKRD53 | c.420C>T p.G140= | Splice Region (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99721616; called by muse, mutect2, varscan2
- APBA1 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV99597338; called by muse, mutect2, varscan2
- ARHGAP6 | c.1344T>G p.F448L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100273660; called by muse, mutect2, varscan2
- ATG13 | c.1348-2A>T p.X450_splice (on ENST00000359513 / NM_001346321.1; = p.X413_splice on NM_014741.4 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/130 reads (14%) | catalogued as COSV100366119; called by muse, mutect2, varscan2
- BRF1 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as rs369638144; called by muse, mutect2, varscan2
- C3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV99837403; called by muse, mutect2, varscan2
- CDKN2A | c.151del p.V51Sfs*2 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as CM065063, COSV58695751; called by mutect2, pindel, varscan2
- CHRDL1 | c.212G>T p.R71L (on ENST00000372045; = p.R77L on NM_145234.4) | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54326285, COSV99488325; called by muse, mutect2, varscan2
- CHST9 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99411171; called by muse, mutect2, varscan2
- CIC | c.1158C>G p.Y386* | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | catalogued as COSV99360428; called by muse, mutect2, varscan2
- CYLC1 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100255621; called by muse, mutect2, varscan2
- CYLC1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1278591476, COSV100255622; called by muse, mutect2, varscan2
- DBR1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV99604659; called by muse, mutect2
- DENND6A | c.1625T>G p.L542* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs1217150037, COSV100231677; called by muse, mutect2, varscan2
- DIDO1 | c.5178G>T p.Q1726H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV99827438; called by muse, mutect2, varscan2
- DNAH8 | c.7316A>T p.N2439I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV59467687; called by muse, mutect2, varscan2
- ECI2 | c.794G>A p.R265K (on ENST00000380118 / NM_206836.3; = p.R235K on NM_006117.2) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV60988322; called by muse, mutect2, varscan2
- EPRS1 | c.3210A>T p.K1070N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100859541; called by muse, mutect2, varscan2
- ESX1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs782015243, COSV101006441; called by muse, mutect2
- EYA1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.882); catalogued as rs181191349; ClinVar: benign; called by muse, mutect2
- HASPIN | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99561680; called by muse, mutect2, varscan2
- IGF2 | c.548G>A p.R183H (on ENST00000434045 / NM_001127598.3; = p.R127H on NM_000612.6) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191719522, COSV100324304; called by muse, mutect2, varscan2
- INPPL1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); catalogued as rs201045134, COSV99996745; called by muse, mutect2, varscan2
- KCNH8 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760239055, COSV100111191, COSV60470016, COSV60473210; called by muse, mutect2, varscan2
- KIAA1217 | c.1093A>T p.S365C | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100287435, COSV56814820; called by muse, mutect2, varscan2
- KIF4B | c.2416C>T p.H806Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs1330641210, COSV101469425; called by muse, mutect2, varscan2
- KLB | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV99962552; called by muse, mutect2, varscan2
- KRT75 | c.777C>T p.D259= | Splice Region (SNP) | VAF 16/69 reads (23%) | catalogued as rs373953042; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1258391158, COSV99524313; called by muse, mutect2, varscan2
- MARK2 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773162629, COSV100159235; called by muse, mutect2, varscan2
- MPDZ | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs367848962, COSV100063655; called by muse, mutect2, varscan2
- MYO1D | c.2410G>A p.V804I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.159); catalogued as COSV100555060; called by muse, mutect2, varscan2
- NUDCD3 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100819445; called by muse, mutect2, varscan2
- OR10G2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs373027971; called by muse, mutect2, varscan2
- OR11H1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99422075; called by mutect2, varscan2
- P2RX2 | c.752G>A p.S251N (on ENST00000343948 / NM_170683.4; = p.S179N on NM_012226.5) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100268629; called by muse, mutect2, varscan2
- PCDH10 | c.2536A>G p.T846A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99994730; called by muse, mutect2, varscan2
- PCDH11X | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV100016023; called by muse, mutect2, varscan2
- PCLO | c.11101G>A p.E3701K | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs369294508; called by muse, mutect2, varscan2
- PLCB1 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100572373, COSV104402690; called by muse, mutect2
- PNMA5 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | catalogued as COSV100721733; called by muse, mutect2, varscan2
- POLR2M | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100221393; called by muse, mutect2, varscan2
- PPP2R5C | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100160212; called by muse, mutect2, varscan2
- PUM2 | c.1390A>T p.M464L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100164073; called by muse, mutect2, varscan2
- RPL3 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.1); catalogued as COSV99335358; called by muse, mutect2, varscan2
- SCP2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101027292; called by muse, mutect2
- SCRIB | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs760633347, COSV100254332; called by mutect2, varscan2
- SEC22A | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as rs758958858, COSV100007176; called by muse, mutect2, varscan2
- SEL1L | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.135); catalogued as COSV100378167; called by muse, mutect2
- SEMA4A | c.551A>T p.H184L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.21); catalogued as COSV100740755; called by muse, mutect2, varscan2
- SERPINA7 | c.570A>T p.Q190H | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV100568527; called by muse, mutect2, varscan2
- SERTM1 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59376072; called by muse, mutect2
- SNTG1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99386694; called by muse, mutect2, varscan2
- TBC1D15 | c.1035+2T>C p.X345_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100042357; called by muse, mutect2, varscan2
- TBCE | c.1159A>G p.I387V (on ENST00000366601; = p.I450V on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs550575040, COSV100783299; called by muse, varscan2
- TBX19 | c.719A>T p.Y240F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100892432; called by muse, mutect2, varscan2
- TGFBI | c.664C>G p.H222D | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV100526740; called by muse, varscan2
- TKT | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99965191; called by muse, mutect2, varscan2
- TLR10 | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs759415048, COSV100458140; called by muse, mutect2, varscan2
- TTC13 | c.328T>A p.C110S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV100793061; called by muse, mutect2, varscan2
- TTN | c.93938C>A p.T31313N (on ENST00000591111; = p.T23889N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | PolyPhen probably damaging (0.997); catalogued as COSV100634353; called by muse, mutect2, varscan2
- TTN | c.10013A>T p.Q3338L (on ENST00000591111; = p.Q3292L on NM_003319.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | PolyPhen benign (0); catalogued as COSV100634355; called by muse, mutect2, varscan2
- U2SURP | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV101204601; called by muse, mutect2, varscan2
- UNC13B | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV101037492; called by muse, mutect2
- UTRN | c.5946T>A p.H1982Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.618); catalogued as COSV100840744; called by muse, mutect2, varscan2
- VEZT | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763560318, COSV54142629; called by muse, mutect2, varscan2
- ARHGDIA | c.58dup p.E20Gfs*3 | Frame Shift Ins (INS) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- DAG1 | c.2317del p.I773Sfs*70 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- RGL2 | c.2183dup p.L729Pfs*28 | Frame Shift Ins (INS) | VAF 20/94 reads (21%) | called by mutect2, pindel, varscan2
- SVIL | c.6374dup p.E2126Rfs*5 (on ENST00000355867 / NM_021738.3; = p.E1700Rfs*5 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- ACTR8 | c.180T>A p.I60= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV99213922; called by muse, mutect2, varscan2
- ANP32A | c.42G>A p.R14= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs373044896; called by muse, mutect2, varscan2
- DIAPH1 | c.1080G>A p.V360= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1457217172, COSV99527377; called by muse, mutect2, varscan2
- EIF2S2 | c.480T>C p.S160= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100895020; called by muse, mutect2, varscan2
- EIF3A | c.771C>T p.H257= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs759767366, COSV100974867; called by muse, mutect2, varscan2
- EPPK1 | c.4998C>A p.A1666= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV73262284; called by muse, mutect2, varscan2
- FBXL3 | c.604C>T p.L202= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs748230433, COSV100842323, COSV100842403; called by muse, mutect2, varscan2
- HTRA1 | c.645C>A p.I215= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100934816, COSV64564463; called by muse, mutect2, varscan2
- NFKB1 | c.1551C>T p.F517= (on ENST00000394820 / NM_001382627.1; = p.F518= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs566062917, COSV99898001; called by muse, mutect2, varscan2
- NXF1 | c.1629G>A p.E543= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV99586530; called by muse, mutect2, varscan2
- OR10G9 | c.129C>T p.I43= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV100901800; called by muse, mutect2, varscan2
- OR6T1 | c.729G>A p.S243= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs138335573, COSV58306231; called by muse, mutect2, varscan2
- PAMR1 | c.1689C>T p.I563= (on ENST00000619888 / NM_001001991.3; = p.I580= on NM_015430.4) | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99553181; called by muse, mutect2, varscan2
- PCNT | c.1926G>T p.G642= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100856152; called by muse, mutect2
- RSAD1 | c.750G>A p.P250= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs561004561, COSV99364434; called by muse, mutect2, varscan2
- TNKS1BP1 | c.741C>T p.S247= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs773632907, COSV100836325; called by muse, mutect2, varscan2
- ZNF746 | c.1701C>T p.T567= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1315789383, COSV61406461; called by muse, mutect2, varscan2
- ZNF772 | c.120G>A p.E40= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV100582949; called by muse, mutect2, varscan2
- ZNF211 | c.*1C>T | 3'UTR (SNP) | VAF 14/101 reads (14%) | catalogued as COSV99560565; called by muse, mutect2, varscan2
